Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QB, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QB-01C (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD

Surgical Pathology Report

Surgical Pathology Report

ICD O-3
Carcinoma, renal cell chromophobe
type
Site: R Kidney NOS
831713
264.9
9124113

PATIENT:
ACCOUNT#:
DOB:
AGE:
ATTENDING:
REQUESTING:
CONTACT NO:
COPIES TO:

SEX: M

MRN:
RECEIVED DATE:
PROCEDURE DATE:
SIGN-OUT DATE:
LOCATION:

ROOM:

DIAGNOSIS: Kidney, right, radical nephrectomy: Renal cell carcinoma, chromophobe cell type, Fuhrman nuclear grade II; no capsular invasion seen; vascular, ureteral and inked surgical margins of resection are free of tumor; no tumor seen in three lymph nodes (0/3); see note.

NOTE:

Kidney Nephrectomy Summary Table Macroscopic

Specimen Type: Radical nephrectomy
Laterality: Right

Tumor Size: 5 x 5 x 4 cm
Focality: Unifocal

Macro Extent of Tumor: Confined to kidney, upper pole, laterally

Microscopic

Histologic Type: Renal cell carcinoma, chromophobe cell type
Histologic Grade: Fuhrman nuclear grade II

Extent of Invasion

Primary Tumor(pT): pT1b
Regional Lymph Nodes(pN): pN0
Distant Metastasis(pM): pMx
Margins: Vascular, ureteric and surgical margins of resection are free of tumor

CLINICAL INFORMATION: Brief Clinical History: yo male with 4.5cm right renal mass, incidental diagnosis, sporadic tumor Requestor Name

Patient Identification

Surgical Pathology Report

File in Section 3: Tissue Examination

Page 1 of 3

[page 2 of 3]
MEDICAL RECORD**Surgical Pathology Report****MRN:****Date of Report:**

Requestor Phone/Pager:
Allocate Order to Protocol:

PROCEDURE: Operative Findings: n/a Post-Operative Diagnosis: same Pre-Operative
Diagnosis: right renal mass

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT

GROSS DESCRIPTION: Received fresh from the OR labeled with the patient's name, medical record number, and "right kidney and adrenal" is a specimen that consists of a radical nephrectomy specimen with attached adrenal gland entirely measuring, in total, 15 x 9 x 6 cm. The specimen is inked in black and bisected revealing a 5 x 5 x 4 cm tumor mass with a brown/yellow cut surface. 40% of the tumor mass is procured for along with representative sections of normal adrenal and kidney. The procurement is performed by on

At the specimen received matches the above description and weighs 240 grams. The kidney is further serially sectioned. The tumor is towards the upper half of the kidney laterally towards the upper lateral pole. The renal capsule appears to be focally adherent over the tumor. The adrenal is well away from the tumor and the fat around the adrenal is not apposed to the tumor. Sections are submitted as follows:

- Vascular and ureteral cut margins
- J and C: Sections from areas suspicious for capsule adherence including up to inked surgical margin
- Representative section from center of tumor
- Section of tumor including renal pelvic fat
- Tumor with adjacent apparent uninvolved kidney
- Tumor including kidney and suprarenal fat
- Adrenal with surrounding fat
- Section from grossly normal kidney.
- J and K: Probable lymph node candidates from the renal hilum

Gross dictated by

No consultants

Patient Identification

[page 3 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name:

MRN:

Date of Report:

Patient Identification

Source: NCI Genomic Data Commons file ed9f771c-ed75-4a23-ae37-347761595f75 (TCGA-KM-A7QB.1EDC857F-C9D2-40B9-A86B-5110D5865B0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).